Somatic mutation profile of tumor specimen TCGA-CF-A7I0-01A (aliquot TCGA-CF-A7I0-01A-22D-A34U-08) from TCGA case TCGA-CF-A7I0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 54.9 years (20,059 days).
Specimen TCGA-CF-A7I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f1becc1-6212-4727-bde5-373f9d8f328a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A7I0-10A (Blood Derived Normal), aliquot TCGA-CF-A7I0-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5e891d4-b8a5-44be-beb6-2cc628104cb6

The open-access MAF lists 56 somatic variants for this specimen: 31 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 24, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRF2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as rs775861500, COSV99605009; called by muse, mutect2, varscan2
- CD27 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56946565; called by muse, varscan2
- CHD1L | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV63613577; called by muse, mutect2, varscan2
- CNNM2 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1366640190, COSV63995805; called by muse, mutect2, varscan2
- COIL | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV53594641; called by muse, mutect2, varscan2
- COL3A1 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58585934; called by muse, mutect2, varscan2
- DCLK1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as rs56185003, COSV55171671, COSV55182610; called by muse, mutect2, varscan2
- DENND1A | c.2131G>A p.G711S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65349359; called by muse, mutect2, varscan2
- DISP3 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53825570, COSV99610324; called by muse, mutect2, varscan2
- FAM193A | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as rs767754109, COSV61193138; called by muse, mutect2, varscan2
- FAM214A | c.133C>G p.H45D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55923665; called by muse, mutect2, varscan2
- GPRIN3 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV60884651; called by muse, mutect2, varscan2
- HTR6 | c.905T>A p.F302Y | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53871861; called by muse, mutect2, varscan2
- KATNA1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV59502154; called by muse, mutect2, varscan2
- KRT12 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV52430540; called by muse, mutect2, varscan2
- LIPE | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.27); catalogued as rs771231913, COSV54922347; called by muse, mutect2, varscan2
- LMBRD2 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56949510; called by muse, mutect2, varscan2
- MUC3A | c.7045G>A p.E2349K | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious, low confidence (0.01); catalogued as rs553559317, COSV60213739; called by muse, mutect2, varscan2
- OR7D4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as COSV58071502; called by muse, mutect2, varscan2
- POLR3A | c.2948C>A p.T983N | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.761); catalogued as rs756864064, COSV64930868; called by muse, mutect2, varscan2
- RIF1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54611807; called by muse, mutect2, varscan2
- SHROOM1 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV60580973; called by muse, mutect2, varscan2
- SLC6A19 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV58670778; called by muse, mutect2, varscan2
- SPTAN1 | c.5884G>T p.E1962* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100823741; called by muse, mutect2, varscan2
- TRIM56 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV60158255; called by muse, mutect2, varscan2
- TTF2 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1399693486, COSV65632406; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2786C>T p.S929L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54436421; called by muse, mutect2, varscan2
- ZBTB32 | c.1223A>T p.Q408L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363040321, COSV52890208; called by muse, mutect2, varscan2
- ZMYM4 | c.2764G>T p.D922Y | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV58909372; called by muse, mutect2, varscan2
- CDKN1A | c.79dup p.S27Kfs*9 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- ABCA4 | c.4281C>T p.F1427= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV64672899; called by muse, mutect2, varscan2
- AFF4 | c.3168T>C p.P1056= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV54793899; called by muse, mutect2, varscan2
- AGBL1 | c.2652C>G p.L884= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs545197071, COSV66855555; called by muse, mutect2, varscan2
- BRINP3 | c.1407C>T p.L469= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as COSV66520876; called by muse, mutect2, varscan2
- CCDC27 | c.741G>A p.Q247= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV53899668; called by muse, mutect2, varscan2
- FAM170A | c.663G>A p.L221= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as COSV58924801; called by muse, mutect2, varscan2
- INTS1 | c.315G>A p.P105= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as rs758467582, COSV67177150; called by muse, mutect2, varscan2
- KRT15 | c.411C>A p.I137= | Silent (SNP) | VAF 48/161 reads (30%) | catalogued as COSV54179025, COSV99563207; called by muse, mutect2, varscan2
- LAMA3 | c.8340C>T p.F2780= (on ENST00000313654 / NM_198129.4; = p.F1171= on NM_000227.6) | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV52533498; called by muse, mutect2, varscan2
- MFSD6L | c.867C>A p.V289= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV61002657; called by muse, mutect2, varscan2
- MTUS2 | c.870G>C p.S290= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV70913127, COSV70916302; called by muse, mutect2, varscan2
- PAFAH2 | c.654G>A p.L218= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV65339416; called by muse, mutect2, varscan2
- PCDHA13 | c.2229C>T p.S743= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV56494255; called by muse, mutect2
- PLXNB1 | c.1701A>G p.S567= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV56488807; called by muse, mutect2, varscan2
- RASSF1 | c.960C>A p.L320= (on ENST00000357043 / NM_170714.2; = p.L316= on NM_007182.5) | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV51700426, COSV51701119; called by muse, mutect2, varscan2
- RMI2 | c.336C>T p.S112= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV56963935; called by muse, mutect2, varscan2
- SGIP1 | c.861C>T p.S287= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV52766601, COSV52781424; called by muse, mutect2
- SHROOM1 | c.1323C>G p.L441= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs986247785, COSV60580957; called by muse, mutect2, varscan2
- SMAD7 | c.810G>A p.K270= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV50989209; called by muse, mutect2, varscan2
- SMURF1 | c.591C>T p.F197= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs772861699, COSV63157025; called by muse, mutect2, varscan2
- TACC3 | c.2472G>T p.L824= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100508826; called by muse, mutect2
- TXLNA | c.525G>A p.L175= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV65314177; called by muse, mutect2, varscan2
- ZNF423 | c.726C>T p.T242= (on ENST00000563137 / NM_001379286.1; = p.T234= on NM_015069.4) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52185379; called by muse, mutect2, varscan2
- ZNF804A | c.2454A>G p.R818= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV56445050; called by muse, mutect2, varscan2
- NBPF25P | n.1688G>C | RNA (SNP) | VAF 42/353 reads (12%) | called by muse, mutect2, varscan2
